TCGA case TCGA-PJ-A5Z8 — Kidney Renal Papillary Cell Carcinoma (TCGA-KIRP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney; Tissue source site: Gundersen Lutheran. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ef4526a-8089-46ba-aa7f-4300ab6bbbe9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 60 years; Vital status: Alive.

Diagnoses (2)
1. Papillary adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8260/3; ICD-10 code: C64.1; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 60.1 years (21,968 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC clinical T: T1a; AJCC clinical N: NX; AJCC clinical M: MX; AJCC clinical stage: Stage I; AJCC pathologic T: T1a; AJCC pathologic N: NX; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 600 days (1.6 years).
   Pathology details: Consistent pathology review: Yes; Prcc type: Type 2.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Serous cystadenocarcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Uterus, NOS; Classification of tumor: Prior primary; AJCC pathologic stage: Stage IV.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Cervix / Uterus.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 113 days; Disease response: Tumor Free.
- Days to follow up: 391 days (1.1 years); Disease response: Tumor Free.
- Days to follow up: 600 days (1.6 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Hemoglobin: Low.
- Platelets: Low.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 111 kg.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-PJ-A5Z8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-PJ-A5Z8-01A-01-TSA: Section location: Top; Percent tumor cells: 78; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 20; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
- Sample TCGA-PJ-A5Z8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-PJ-A5Z8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Kidney Papillary Renal Cell Carcinoma; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Hemoglobin level: Low; Lymph nodes examined: No; Tobacco smoking history indicator: 1; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; Treatment outcome at TCGA followup: Complete Remission/Response; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Uterus; Other malignancy histological type: Uterine serous endometrial adenocarcinoma.
- Other malignancy form, Surgery: Other malignancy surgery type: Total Hysterectomy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 600 days; disease-specific survival: no event (censored), 600 days; disease-free interval: no event (censored), 600 days; progression-free interval: no event (censored), 600 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-PJ-A5Z8-01A-11D-A28F-01): tumor purity 0.45, ploidy 1.89, whole-genome doublings 0.
